Somatic mutation profile of tumor specimen TCGA-HR-A2OH-06A (aliquot TCGA-HR-A2OH-06A-11D-A197-08) from TCGA case TCGA-HR-A2OH, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 50.5 years (18,433 days).
Specimen TCGA-HR-A2OH-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f3dbf6d7-daa9-4cc5-baf5-1da3a4c6b917.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HR-A2OH-10A (Blood Derived Normal), aliquot TCGA-HR-A2OH-10A-01D-A199-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5cd03113-946f-4247-9baa-da4a190d4077

The open-access MAF lists 136 somatic variants for this specimen: 87 protein-altering or splice-affecting, 44 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 79, Silent 44, Nonsense Mutation 5, Intron 2, Splice Region 2, RNA 2, Frame Shift Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- IRF6 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.367); catalogued as rs28942093, CM022374, COSV65420110; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PKHD1 | c.2341C>T p.R781* | Nonsense Mutation (SNP) | VAF 13/100 reads (13%) | catalogued as rs398124478, CM051135, COSV100584810, COSV61864770; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.112C>T p.P38S | Missense Mutation (SNP) | VAF 12/43 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs587780004, COSV100911304, COSV64289791; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- PTEN | c.113C>T p.P38L | Missense Mutation (SNP) | VAF 12/43 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CM131938, COSV64289920, COSV64290011, COSV64297199; called by muse, mutect2, varscan2
- ABCB1 | c.1725G>A p.K575= | Splice Region (SNP) | VAF 13/43 reads (30%) | catalogued as COSV55959491; called by muse, mutect2, varscan2
- ACSM1 | c.47C>T p.S16F | Missense Mutation (SNP) | VAF 47/256 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV54637531; called by muse, mutect2, varscan2
- ACSM2B | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); catalogued as COSV61658676, COSV61659320; called by muse, mutect2
- APOB | c.8725G>A p.E2909K | Missense Mutation (SNP) | VAF 145/565 reads (26%) | SIFT tolerated (0.41); PolyPhen benign (0.321); catalogued as rs200824333; called by muse, mutect2, varscan2
- ARAP2 | c.4168C>T p.H1390Y | Missense Mutation (SNP) | VAF 40/115 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58288234; called by muse, mutect2, varscan2
- BEND2 | c.791G>A p.R264Q | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs374044388, COSV66215791, COSV66216816; called by muse, mutect2, varscan2
- C14orf39 | c.1409C>T p.P470L | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100407607, COSV100408281; called by muse, mutect2, varscan2
- C14orf39 | c.1408C>T p.P470S | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.799); catalogued as COSV58785143; called by muse, mutect2, varscan2
- CCDC158 | c.2551C>T p.P851S | Missense Mutation (SNP) | VAF 58/166 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV66356873; called by muse, mutect2, varscan2
- CDCA8 | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.984); catalogued as COSV59240082; called by muse, mutect2, varscan2
- CDH5 | c.833G>A p.G278D | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); catalogued as COSV58519236; called by muse, mutect2, varscan2
- CLK3 | c.584C>T p.S195F (on ENST00000395066 / NM_001130028.1; = p.S47F on NM_003992.4) | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as COSV61414332; called by muse, mutect2, varscan2
- COL22A1 | c.4790G>A p.G1597E | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV57334762; called by muse, mutect2, varscan2
- COL22A1 | c.4789G>A p.G1597R | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100277053, COSV100278442; called by muse, mutect2, varscan2
- COL23A1 | c.1247C>T p.P416L | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV101178754, COSV101179926; called by muse, mutect2, varscan2
- COPB2 | c.1424A>G p.E475G | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.117); catalogued as rs1347322165, COSV60813528; called by muse, mutect2, varscan2
- CWH43 | c.1324G>A p.E442K | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.033); catalogued as COSV56937827; called by muse, mutect2, varscan2
- DGKD | c.566C>T p.S189L (on ENST00000264057 / NM_152879.3; = p.S145L on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/143 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.657); catalogued as rs1325916707, COSV51057863; called by muse, mutect2
- DMTN | c.344C>T p.P115L | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.66); PolyPhen benign (0.01); catalogued as COSV56113954; called by muse, mutect2, varscan2
- DNAH5 | c.12415C>T p.P4139S | Missense Mutation (SNP) | VAF 32/121 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.901); catalogued as COSV54209617; called by muse, mutect2, varscan2
- DNAH9 | c.8255G>A p.S2752N | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV52368032; called by muse, mutect2, varscan2
- DRD1 | c.1126G>A p.E376K | Missense Mutation (SNP) | VAF 32/130 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.101); catalogued as COSV67105061; called by muse, mutect2, varscan2
- FAT2 | c.12583C>T p.H4195Y | Missense Mutation (SNP) | VAF 43/187 reads (23%) | SIFT tolerated (0.41); PolyPhen benign (0.099); catalogued as COSV55826580; called by muse, mutect2, varscan2
- GARNL3 | c.1928A>G p.Y643C | Missense Mutation (SNP) | VAF 33/261 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs750579348, COSV59229144; called by muse, mutect2, varscan2
- GC | c.1069C>T p.P357S | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as COSV56738991; called by muse, mutect2, varscan2
- GPAT4 | c.370G>T p.E124* | Nonsense Mutation (SNP) | VAF 24/132 reads (18%) | catalogued as COSV67841759; called by muse, mutect2, varscan2
- GPHB5 | c.183G>A p.W61* | Nonsense Mutation (SNP) | VAF 6/44 reads (14%) | catalogued as COSV58486926, COSV58487106; called by muse, mutect2, varscan2
- GRB7 | c.401G>A p.R134Q | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.103); catalogued as rs150749308; called by muse, mutect2, varscan2
- GRIK4 | c.742C>T p.L248= | Splice Region (SNP) | VAF 24/89 reads (27%) | catalogued as COSV70805465; called by muse, mutect2, varscan2
- GRIP2 | c.2383C>T p.H795Y (on ENST00000619221; = p.H698Y on NM_001080423.4) | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV56123639; called by muse, mutect2, varscan2
- GRM3 | c.1266G>A p.M422I | Missense Mutation (SNP) | VAF 70/214 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.617); catalogued as rs773308323, COSV64477378; called by muse, mutect2, varscan2
- HCN2 | c.469G>A p.G157S | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.74); PolyPhen benign (0.184); catalogued as COSV52117582; called by mutect2, varscan2
- HDC | c.1682C>T p.T561I | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.036); catalogued as rs766150542, COSV51077206; called by muse, mutect2, varscan2
- HIVEP3 | c.3295C>T p.P1099S | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV56012724; called by muse, mutect2, varscan2
- HTR3A | c.152C>T p.P51L | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55470969; called by muse, mutect2, varscan2
- IGSF9B | c.929G>A p.G310E | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.978); catalogued as COSV58071191; called by muse, mutect2
- IKBIP | c.152C>T p.S51L | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs1402386690, COSV54490816; called by muse, mutect2, varscan2
- IREB2 | c.2099C>T p.S700F | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV51925487; called by muse, mutect2, varscan2
- ITPR1 | c.6527C>A p.P2176H (on ENST00000354582; = p.P2121H on NM_002222.7) | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV56996991, COSV57007777; called by mutect2, varscan2
- KRTAP10-4 | c.251C>T p.S84F | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as rs782236314, COSV59973988; called by muse, mutect2, varscan2
- LCK | c.805A>G p.K269E | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.048); catalogued as COSV60742063; called by muse, mutect2
- LDLRAP1 | c.376G>A p.D126N | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.262); catalogued as rs763971300, COSV65474041, COSV65474291; called by muse, mutect2, varscan2
- LMTK3 | c.496C>T p.L166F | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54315981; called by muse, mutect2, varscan2
- LRBA | c.2957C>T p.T986I | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as COSV63961297; called by muse, mutect2, varscan2
- LRRTM4 | c.1231C>T p.P411S | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV69141223; called by muse, mutect2, varscan2
- METTL7B | c.655G>A p.E219K | Missense Mutation (SNP) | VAF 41/116 reads (35%) | SIFT tolerated (0.37); PolyPhen benign (0.011); catalogued as rs776219569, COSV57693174; called by muse, mutect2, varscan2
- MPP2 | c.814G>A p.E272K (on ENST00000461854 / NM_001278372.2; = p.E248K on NM_005374.5) | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52238834; called by muse, mutect2, varscan2
- MYH2 | c.3739G>T p.A1247S | Missense Mutation (SNP) | VAF 27/137 reads (20%) | SIFT tolerated (0.52); PolyPhen benign (0.015); catalogued as COSV55445223; called by muse, mutect2, varscan2
- MYH4 | c.1934G>A p.G645D | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as COSV55123707; called by muse, mutect2, varscan2
- MYLK4 | c.523G>A p.D175N | Missense Mutation (SNP) | VAF 33/149 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0.047); catalogued as rs750454547, COSV51146484; called by muse, mutect2, varscan2
- NAALADL2 | c.821C>T p.A274V | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.378); catalogued as COSV69159089; called by muse, mutect2, varscan2
- NDST3 | c.584T>A p.I195N | Missense Mutation (SNP) | VAF 42/113 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV56625432; called by muse, mutect2, varscan2
- NEDD9 | c.362C>T p.P121L | Missense Mutation (SNP) | VAF 31/128 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV65159349; called by muse, mutect2, varscan2
- NPSR1 | c.245G>A p.R82K | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.6); catalogued as COSV62205779; called by muse, mutect2, varscan2
- OR13H1 | c.128G>A p.G43E | Missense Mutation (SNP) | VAF 39/123 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.215); catalogued as COSV58548213; called by muse, mutect2, varscan2
- OR2L3 | c.444G>A p.W148* | Nonsense Mutation (SNP) | VAF 13/93 reads (14%) | catalogued as rs780035611, COSV63455742, COSV63456116; called by muse, mutect2, varscan2
- OR52R1 | c.926G>A p.G309E | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.079); catalogued as COSV61888087; called by muse, mutect2, varscan2
- PBXIP1 | c.779A>G p.D260G | Missense Mutation (SNP) | VAF 19/114 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV63777570; called by muse, mutect2, varscan2
- PCDHA7 | c.1549G>A p.V517M | Missense Mutation (SNP) | VAF 12/145 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100971480; called by muse, mutect2
- PELP1 | c.1537G>A p.G513R | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.634); catalogued as COSV52586114; called by muse, mutect2, varscan2
- PELP1 | c.1536A>T p.K512N | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV99342859; called by muse, mutect2, varscan2
- PEX1 | c.2178A>C p.Q726H | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV50410213; called by muse, mutect2, varscan2
- PPP1R13B | c.61C>T p.P21S | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52455092; called by muse, mutect2
- PSMB11 | c.598G>A p.E200K | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV57462678; called by muse, mutect2, varscan2
- PTGES3L-AARSD1 | c.832A>G p.T278A (on ENST00000421990 / NM_001136042.2; = p.T260A on NM_025267.3) | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as COSV64184101; called by muse, mutect2, varscan2
- PTPRT | c.982C>T p.R328C | Missense Mutation (SNP) | VAF 53/124 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.178); catalogued as rs724159835, COSV61966941; called by muse, mutect2, varscan2
- RBAK | c.464G>A p.G155E | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.998); catalogued as rs987434573, COSV100806660; called by muse, mutect2, varscan2
- RNF169 | c.899G>A p.R300K | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as COSV55134769; called by muse, mutect2, varscan2
- RNF213 | c.6004G>A p.V2002M | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs756735067, COSV60403142; called by muse, mutect2, varscan2
- SHANK1 | c.448C>T p.P150S | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53258577; called by muse, mutect2, varscan2
- SHFL | c.371C>T p.P124L | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV53463308; called by muse, mutect2
- SLC17A8 | c.503C>T p.S168L | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs751259606, COSV60122777; called by muse, mutect2, varscan2
- SLC22A1 | c.1316G>A p.R439Q | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs561378730, COSV61452408; called by muse, mutect2, varscan2
- SLC29A2 | c.118C>T p.Q40* | Nonsense Mutation (SNP) | VAF 34/140 reads (24%) | catalogued as COSV60803943; called by muse, mutect2, varscan2
- SPHKAP | c.2992C>T p.P998S | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60875038; called by muse, mutect2, varscan2
- SPTA1 | c.643G>A p.V215I | Missense Mutation (SNP) | VAF 47/161 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.062); catalogued as COSV63757474; called by muse, mutect2, varscan2
- STAG1 | c.115C>T p.R39C | Missense Mutation (SNP) | VAF 52/205 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as rs747804278, COSV52619652; called by muse, mutect2, varscan2
- TNR | c.2788G>A p.E930K | Missense Mutation (SNP) | VAF 25/123 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.332); catalogued as rs531733667, COSV54868765; called by muse, mutect2, varscan2
- TTN | c.12739G>A p.E4247K (on ENST00000591111; = p.E4201K on NM_003319.4) | Missense Mutation (SNP) | VAF 6/63 reads (10%) | catalogued as rs746672079, COSV60169973; ClinVar: uncertain significance; called by mutect2, varscan2
- ZNF121 | c.209C>T p.A70V | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.023); catalogued as COSV57552245; called by muse, mutect2, varscan2
- ZSCAN1 | c.124C>T p.R42W | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373405954; called by mutect2, varscan2
- HSP90AB1 | c.1882del p.I628Sfs*56 | Frame Shift Del (DEL) | VAF 16/134 reads (12%) | called by mutect2, pindel, varscan2
- ACSM2B | c.174G>A p.E58= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as COSV61659316; called by muse, mutect2
- AGBL1 | c.2421G>A p.E807= | Silent (SNP) | VAF 9/60 reads (15%) | catalogued as COSV101224160, COSV66868548; called by muse, mutect2, varscan2
- CARD8 | c.1539C>T p.A513= (on ENST00000651546 / NM_001184900.3; = p.A463= on NM_014959.5 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 39/235 reads (17%) | catalogued as rs770975518, COSV62874749; called by muse, mutect2, varscan2
- CERS2 | c.261C>T p.F87= | Silent (SNP) | VAF 16/51 reads (31%) | catalogued as COSV54990065; called by muse, mutect2, varscan2
- CLECL1 | c.213C>T p.F71= | Silent (SNP) | VAF 21/71 reads (30%) | catalogued as COSV59931945; called by muse, mutect2, varscan2
- CLPTM1L | c.567C>T p.S189= | Silent (SNP) | VAF 10/63 reads (16%) | catalogued as COSV57992030; called by muse, mutect2, varscan2
- CPNE3 | c.888G>A p.V296= | Silent (SNP) | VAF 11/55 reads (20%) | catalogued as COSV52209130; called by muse, mutect2, varscan2
- CPSF4 | c.129C>T p.F43= | Silent (SNP) | VAF 48/304 reads (16%) | catalogued as rs770988515, COSV52856695, COSV52858800, COSV99462180; called by muse, mutect2, varscan2
- CYP2C18 | c.549C>T p.F183= | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as COSV53672007; called by muse, mutect2, varscan2
- CYP2C8 | c.937C>T p.L313= | Silent (SNP) | VAF 24/99 reads (24%) | catalogued as COSV64878417; called by muse, mutect2, varscan2
- DNM3 | c.2175G>A p.R725= (on ENST00000355305 / NM_001350206.2; = p.R719= on NM_015569.5) | Silent (SNP) | VAF 28/102 reads (27%) | catalogued as rs754060305, COSV62464129; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.2463G>A p.V821= | Silent (SNP) | VAF 18/60 reads (30%) | catalogued as COSV100668533; called by muse, mutect2, varscan2
- EXTL3 | c.786C>T p.S262= | Silent (SNP) | VAF 6/68 reads (9%) | catalogued as COSV55039643; called by muse, mutect2
- GJB3 | c.597C>T p.I199= | Silent (SNP) | VAF 10/55 reads (18%) | catalogued as rs1016981705, COSV64904742; called by muse, mutect2, varscan2
- GLIS3 | c.621G>A p.P207= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as rs1295106423, COSV60933505; called by muse, mutect2, varscan2
- GLRA1 | c.408C>T p.F136= | Silent (SNP) | VAF 10/89 reads (11%) | catalogued as COSV51007438, COSV51008702; called by muse, mutect2, varscan2
- GTSF1 | c.460C>T p.L154= | Silent (SNP) | VAF 24/47 reads (51%) | catalogued as COSV59939229; called by muse, mutect2, varscan2
- ITGA8 | c.1074G>A p.G358= | Silent (SNP) | VAF 15/75 reads (20%) | catalogued as rs373648949, COSV65234420; called by muse, mutect2, varscan2
- KCTD18 | c.237C>T p.P79= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as COSV63344980; called by muse, mutect2, varscan2
- KRTAP5-2 | c.315G>A p.K105= | Silent (SNP) | VAF 30/99 reads (30%) | catalogued as rs766128627, COSV101295065, COSV69015152, COSV69015221; called by muse, mutect2, varscan2
- LRP1B | c.3789C>T p.I1263= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as COSV67257859; called by muse, mutect2, varscan2
- MED23 | c.1350C>T p.S450= | Silent (SNP) | VAF 9/51 reads (18%) | catalogued as COSV63435631; called by muse, mutect2, varscan2
- MPHOSPH8 | c.834C>T p.D278= | Silent (SNP) | VAF 21/138 reads (15%) | catalogued as COSV64057077; called by muse, mutect2, varscan2
- MUC16 | c.41232C>T p.N13744= | Silent (SNP) | VAF 44/201 reads (22%) | catalogued as rs370065271; called by muse, mutect2, varscan2
- MUC16 | c.27999C>T p.I9333= | Silent (SNP) | VAF 34/156 reads (22%) | catalogued as rs749137600, COSV67483437; called by muse, mutect2, varscan2
- NECTIN4 | c.1170G>A p.L390= | Silent (SNP) | VAF 6/60 reads (10%) | catalogued as rs1222186578, COSV63513676; called by muse, mutect2
- NLRP13 | c.1032C>T p.I344= | Silent (SNP) | VAF 17/104 reads (16%) | catalogued as rs915473889, COSV61623552; called by muse, mutect2, varscan2
- NXNL1 | c.150C>T p.F50= | Silent (SNP) | VAF 23/87 reads (26%) | catalogued as COSV57325084; called by muse, mutect2, varscan2
- OR10T2 | c.750C>T p.V250= | Silent (SNP) | VAF 18/80 reads (23%) | catalogued as COSV57782792; called by muse, mutect2, varscan2
- OR10W1 | c.160C>T p.L54= | Silent (SNP) | VAF 18/67 reads (27%) | catalogued as COSV67720759; called by muse, mutect2, varscan2
- OR1S2 | c.414G>A p.A138= | Silent (SNP) | VAF 30/95 reads (32%) | catalogued as rs145253819; called by muse, mutect2, varscan2
- OR2A2 | c.460C>T p.L154= | Silent (SNP) | VAF 35/110 reads (32%) | catalogued as rs1334813151, COSV68872289; called by muse, mutect2, varscan2
- PADI1 | c.153C>T p.F51= | Silent (SNP) | VAF 32/135 reads (24%) | catalogued as COSV64939026; called by muse, mutect2, varscan2
- PCLO | c.4524G>A p.E1508= | Silent (SNP) | VAF 11/71 reads (15%) | catalogued as COSV61656626; called by muse, mutect2, varscan2
- RERE | c.4008C>T p.P1336= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as COSV61947737; called by muse, mutect2
- RTF2 | c.366C>G p.P122= | Silent (SNP) | VAF 9/50 reads (18%) | catalogued as COSV50130341; called by muse, mutect2
- RYR3 | c.5529C>T p.F1843= | Silent (SNP) | VAF 4/23 reads (17%) | catalogued as COSV66779041; called by muse, mutect2
- SERAC1 | c.1920T>A p.T640= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as COSV65597570; called by muse, mutect2, varscan2
- SUPT5H | c.2298G>C p.G766= | Silent (SNP) | VAF 19/54 reads (35%) | catalogued as COSV63241377; called by muse, mutect2, varscan2
- TEAD2 | c.651C>T p.A217= | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as COSV60874590; called by muse, mutect2
- TICRR | c.1608C>T p.C536= | Silent (SNP) | VAF 12/70 reads (17%) | catalogued as rs1427245397, COSV51545312; called by muse, mutect2, varscan2
- TTC23 | c.474G>A p.E158= | Silent (SNP) | VAF 35/195 reads (18%) | catalogued as rs1180788047, COSV50443435, COSV50444283; called by muse, mutect2, varscan2
- XIRP2 | c.5544A>G p.K1848= (on ENST00000628543; = p.K2023= on NM_152381.6) | Silent (SNP) | VAF 14/58 reads (24%) | catalogued as rs777569844, COSV54698255, COSV54724015; called by muse, mutect2, varscan2
- ZNF518B | c.549A>G p.K183= | Silent (SNP) | VAF 39/124 reads (31%) | catalogued as COSV58724031; called by muse, mutect2, varscan2
- COL11A1 | c.898-285G>A | Intron (SNP) | VAF 23/130 reads (18%) | catalogued as COSV62175929; called by muse, mutect2, varscan2
- DCAF13 | c.-11G>A | 5'UTR (SNP) | VAF 16/50 reads (32%) | catalogued as COSV52566515; called by muse, mutect2, varscan2
- MIR518D | n.25G>A | RNA (SNP) | VAF 13/75 reads (17%) | catalogued as rs759964464; called by muse, mutect2, varscan2
- SSPOP | n.10125C>T | RNA (SNP) | VAF 7/31 reads (23%) | catalogued as COSV65131540; called by muse, mutect2, varscan2
- TTN | c.10361-3825A>T | Intron (SNP) | VAF 15/87 reads (17%) | catalogued as COSV100612165; called by muse, mutect2, varscan2
